Gene-level copy-number profile of tumor specimen TCGA-DE-A4MD-06A from TCGA case TCGA-DE-A4MD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 71.7 years (26,179 days).
Specimen TCGA-DE-A4MD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.542f6e04-b458-451e-88fc-cc08d9bbde1b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DE-A4MD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 373 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f08d6b9-c0bc-4279-b657-891fba113a43

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,376; copy number 1: 2,183; copy number 2: 52,673; copy number 3: 2,806; copy number 4: 40; copy number 5: 110; copy number 6: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DE-A4MD-06A-11D-A256-01): tumor purity 0.58, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 172 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:175,315,194–175,743,616, 2 genes, copy number 5 (within-gene range 3–5): TNR, TNR-IT1.
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–91,723,605, 102 genes, copy number 5 (broad region; genes not listed).
- chr14:105,785,505–106,117,204, 62 genes, copy number 6 (broad region; genes not listed).
- chr17:46,193,576–46,268,694, 5 genes, copy number 5: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 2,183. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
